Somatic mutation profile of tumor specimen MP2PRT-PATVJP-TMP1-A (aliquot MP2PRT-PATVJP-TMP1-A-1-0-D-A81P-36) from MP2PRT case MP2PRT-PATVJP, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.2 years (2,269 days).
Specimen MP2PRT-PATVJP-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d655b84c-d7ee-467b-ba28-180f72b669bb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATVJP-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATVJP-NB1-A-1-0-D-A81P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3866edd1-b538-4c1b-9bc7-dd6382052830

The open-access MAF lists 16 somatic variants for this specimen: 11 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 3, 5'UTR 1, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FERD3L | c.338G>A p.R113Q | Missense Mutation (SNP) | VAF 186/454 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51762396; called by muse, varscan2
- GRK1 | c.152G>A p.R51H | Missense Mutation (SNP) | VAF 169/469 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.268); catalogued as rs758788971, COSV59552766; called by muse, mutect2, varscan2
- PEG3 | c.1178G>A p.R393H | Missense Mutation (SNP) | VAF 85/254 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.036); catalogued as rs1046467329, COSV55638306; called by muse, mutect2, varscan2
- TNXB | c.8560G>A p.V2854I (on ENST00000647633; = p.V2607I on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 63/222 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as rs757463918; called by muse, mutect2, varscan2
- ZNF821 | c.818G>A p.R273Q (on ENST00000425432 / NM_001376297.1; = p.R231Q on NM_017530.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 174/452 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as rs1428226673; called by muse, mutect2, varscan2
- CNOT3 | c.2151_2152insCCTCCTATGA p.E718Pfs*6 | Frame Shift Ins (INS) | VAF 120/416 reads (29%) | called by pindel, varscan2
- HIVEP1 | c.4305A>C p.L1435F | Missense Mutation (SNP) | VAF 96/258 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- INSIG2 | c.268T>C p.C90R | Missense Mutation (SNP) | VAF 91/247 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.609); called by muse, mutect2, varscan2
- NPAS3 | c.2011C>T p.R671W (on ENST00000356141 / NM_001164749.2; = p.R639W on NM_022123.3) | Missense Mutation (SNP) | VAF 22/671 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- PCED1B | c.349G>A p.D117N | Missense Mutation (SNP) | VAF 194/464 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PKHD1L1 | c.7922C>T p.T2641I | Missense Mutation (SNP) | VAF 157/368 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ESPN | c.2172G>A p.P724= | Silent (SNP) | VAF 235/611 reads (38%) | catalogued as rs781377643; called by muse, mutect2, varscan2
- FBXO46 | c.1251C>T p.D417= | Silent (SNP) | VAF 262/665 reads (39%) | catalogued as rs1470014886, COSV58347975; called by muse, mutect2, varscan2
- TPST2 | c.774C>T p.I258= | Silent (SNP) | VAF 155/442 reads (35%) | catalogued as rs775980485, COSV100113937; called by muse, mutect2, varscan2
- AC092070.2 | n.1615A>G | RNA (SNP) | VAF 51/128 reads (40%) | called by muse, mutect2, varscan2
- TENT5A | c.-261G>C | 5'UTR (SNP) | VAF 19/624 reads (3%) | called by muse, mutect2
